CCDI case PBCBRZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/1282b925-3b8a-4914-8c47-129c60f721eb

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 12.9 years (4,707 days).

Biospecimens (3 samples)
- Sample 0DQB20: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DQB2I, 0DQB2T (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
